TCGA case TCGA-DV-5565 — Kidney Renal Clear Cell Carcinoma (TCGA-KIRC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Kidney; Tissue source site: NCI Urologic Oncology Branch. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/f6d28a1d-6691-4ac1-8afb-ab0e7dcef867

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 59 years; Vital status: Alive.

Diagnoses (3)
1. Clear cell adenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8310/3; ICD-10 code: C64.9; Tissue or organ of origin: Kidney, NOS; Site of resection or biopsy: Kidney, NOS; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 59.3 years (21,642 days); Year of diagnosis: 2007; AJCC pathologic T: T1a; AJCC pathologic N: NX; AJCC pathologic M: M0; AJCC pathologic stage: Stage I; Tumor grade: G2; Prior malignancy: yes; Synchronous malignancy: No; Prior treatment: No.
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Vandetanib; Initial disease status: Recurrent Disease; Days to treatment start: 1,189 days (3.3 years); Number of cycles: 6; Treatment outcome: Treatment Ongoing; Prescribed dose: 200; Prescribed dose units: mg; Route of administration: Oral.
2. Neuroendocrine carcinoma, NOS: ICD-O-3 morphology code: 8246/3; Tissue or organ of origin: Pancreas, NOS; Classification of tumor: Prior primary; AJCC staging edition: 6th; AJCC pathologic N: NX; AJCC pathologic M: MX.
   Recorded as not given: Pharmaceutical Therapy, NOS; Radiation Therapy, NOS.
3. Prior malignancy of the kidney (histology not recorded by GDC). Laterality: Bilateral.
   Recorded as not given: Pharmaceutical Therapy, NOS; Radiation Therapy, NOS.

Follow-up (6 entries)
- Days to follow up: 404 days (1.1 years); Disease response: With Tumor.
- Days to follow up: 768 days (2.1 years); Disease response: With Tumor.
- Days to follow up: 1,110 days (3.0 years); Disease response: With Tumor.
- Days to follow up: 1,329 days (3.6 years); Disease response: With Tumor.
- Karnofsky performance status: 100; ECOG performance status: 0; Timepoint: Other.
- Karnofsky performance status: 90; ECOG performance status: 1; Timepoint: Preoperative.

Molecular and laboratory tests
- Hemoglobin: Normal.
- Lactate Dehydrogenase: Elevated.
- Calcium: Normal.
- Platelets: Low.
- Leukocytes: Elevated.

Exposures
- Exposure type: Tobacco.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-DV-5565-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 1.7; Intermediate dimension: 0.8; Shortest dimension: 0.3.
  Slide TCGA-DV-5565-01A-01-TS1: Section location: Top; Percent tumor cells: 85; Percent tumor nuclei: 85; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 15.
  Slide TCGA-DV-5565-01A-01-BS1: Section location: Bottom; Percent tumor cells: 85; Percent tumor nuclei: 85; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 15.
- Sample TCGA-DV-5565-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-DV-5565-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Kidney Clear Cell Renal Carcinoma; History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Tumor status: With tumor; Lymph nodes examined: No.
- Drug treatment: Regimen number: 01; Pharmaceutical therapy drug name: ZD6474; Therapy regimen: Recurrence.
- Drug treatment, Route of administrations: Route of administration: PO.
- Other malignancy form 1: Malignancy type: Prior Malignancy; Other malignancy laterality: Both.
- Other malignancy form 2: Malignancy type: Prior Malignancy; Other malignancy anatomic site: Pancreas; Other malignancy histological type: Neuroendocrine Tumor.
- Other malignancy form 2, Surgery: Days from index date to other malignancy surgery: -473.

GDC annotations on this case (curator notes; quoted as recorded):
- Prior malignancy: Prior malignancy pancreas cancer. Prior malignancy bilateral kidney cancer x2. No systemic chemotherapy or radiation for any malignancies.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 1,329 days; disease-specific survival: no event (censored), 1,329 days; progression-free interval: no event (censored), 1,329 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-DV-5565-01A-01D-1530-01): tumor purity 0.7, ploidy 1.92, whole-genome doublings 0.
